Somatic mutation profile of tumor specimen TCGA-B9-5156-01A (aliquot TCGA-B9-5156-01A-01D-1589-08) from TCGA case TCGA-B9-5156, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 51.6 years (18,841 days).
Specimen TCGA-B9-5156-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 581e2b0e-5606-453f-9779-081bb5957f4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-5156-10A (Blood Derived Normal), aliquot TCGA-B9-5156-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8e49900-872a-49db-9abd-619ae0e605b5

The open-access MAF lists 89 somatic variants for this specimen: 68 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 19, Frame Shift Ins 4, Frame Shift Del 3, In Frame Del 2, Nonsense Mutation 1, 3'UTR 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS8 | c.1487C>A p.A496D | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774175487, COSV57293279; called by muse, mutect2, varscan2
- AMFR | c.1010A>G p.N337S | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as rs1341972825, COSV51921317; called by muse, mutect2, varscan2
- AMHR2 | c.1456G>C p.D486H | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57685740; called by muse, mutect2, varscan2
- ANKMY1 | c.589A>C p.N197H | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV56034055; called by muse, mutect2, varscan2
- ANKRD10 | c.1033T>A p.C345S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV57443747; called by muse, mutect2, varscan2
- ATR | c.3001G>T p.D1001Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63386469; called by muse, mutect2, varscan2
- BOC | c.739A>C p.S247R | Missense Mutation (SNP) | VAF 61/275 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.034); catalogued as COSV56350753; called by muse, mutect2, varscan2
- CHTF18 | c.1342C>G p.L448V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50100592; called by muse, mutect2
- DARS1 | c.1031dup p.R345Kfs*6 | Frame Shift Ins (INS) | VAF 40/148 reads (27%) | catalogued as rs1319087389; called by mutect2, pindel, varscan2
- EP300 | c.61C>G p.P21A | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54332683; called by muse, mutect2, varscan2
- EXOSC7 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV55556569; called by muse, mutect2, varscan2
- FBXL5 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1251243997, COSV58010979; called by muse, mutect2, varscan2
- FITM2 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV67679171; called by muse, mutect2, varscan2
- HMCN1 | c.16852A>G p.I5618V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54900561; called by muse, mutect2, varscan2
- KANK2 | c.218T>A p.L73Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV62007975; called by muse, mutect2, varscan2
- KDM4B | c.916C>A p.Q306K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen possibly damaging (0.851); catalogued as COSV50220723; called by muse, mutect2, varscan2
- LARS1 | c.2956A>G p.M986V (on ENST00000394434 / NM_020117.11; = p.M959V on NM_016460.3) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1173091638, COSV50976155; called by muse, mutect2, varscan2
- LIMK1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as COSV60281454; called by muse, mutect2, varscan2
- LRRN2 | c.1042A>G p.S348G | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65783770; called by muse, mutect2, varscan2
- LY75-CD302 | c.5165A>G p.K1722R | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as COSV52033273; called by muse, mutect2, varscan2
- MAP2K2 | c.97A>C p.N33H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV53565303; called by muse, mutect2, varscan2
- MUC21 | c.388A>T p.S130C | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.54); catalogued as COSV66220850; called by muse, varscan2
- MYH6 | c.2906A>C p.E969A | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV62450394; called by muse, mutect2, varscan2
- MYH7 | c.1563T>G p.I521M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV62519220; called by muse, mutect2
- MYH9 | c.839T>A p.L280H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV53386193; called by muse, mutect2, varscan2
- NLRP14 | c.842A>C p.Q281P | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as COSV55067094; called by muse, mutect2, varscan2
- NOSIP | c.176+1G>C p.X59_splice | Splice Site (SNP) | VAF 3/13 reads (23%) | catalogued as rs150449733, COSV59198812; called by muse, mutect2
- PDGFRB | c.1193C>A p.A398D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55804609; called by muse, mutect2, varscan2
- PDZK1 | c.510G>T p.M170I | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.173); catalogued as COSV61092249; called by muse, mutect2, varscan2
- PEX12 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV56778046; called by muse, mutect2, varscan2
- PKHD1 | c.5168G>C p.R1723T | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61875397; called by muse, mutect2, varscan2
- PNPT1 | c.503T>C p.L168P | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53177299; called by muse, mutect2, varscan2
- POGZ | c.1676C>A p.T559N | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV55035743; called by muse, mutect2, varscan2
- PRPF4B | c.753A>C p.K251N | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV61784190; called by muse, mutect2, varscan2
- PXDNL | c.1768G>C p.V590L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV62487324; called by muse, mutect2, varscan2
- RNF152 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.5); catalogued as COSV57185467; called by muse, mutect2, varscan2
- ROBO1 | c.1191A>T p.Q397H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.539); catalogued as COSV71394334; called by muse, mutect2
- RPN1 | c.971G>A p.G324D | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56190045; called by muse, mutect2, varscan2
- SEC23A | c.1628T>A p.L543H | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56974045; called by muse, mutect2, varscan2
- SLC3A1 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53222601; called by muse, mutect2, varscan2
- STYXL1 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.12); catalogued as COSV50388750; called by muse, mutect2, varscan2
- STYXL1 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV50388765; called by muse, mutect2, varscan2
- SYTL2 | c.1229T>A p.M410K | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV60359139; called by muse, mutect2, varscan2
- TERT | c.1708A>C p.K570Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57214731; called by muse, mutect2, varscan2
- THAP12 | c.1223T>A p.L408H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as COSV52610651; called by muse, mutect2, varscan2
- THNSL2 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.862); catalogued as rs748203932, COSV59082934; called by muse, mutect2, varscan2
- TMBIM6 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 67/301 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV57279579; called by muse, mutect2, varscan2
- TMEM67 | c.1228A>T p.I410F | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV60039395; called by muse, mutect2, varscan2
- TOR1A | c.827A>C p.H276P | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52213258; called by muse, mutect2, varscan2
- TRIM43 | c.469A>T p.N157Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV55528193; called by muse, mutect2, varscan2
- UBR3 | c.3745C>G p.R1249G | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV55849470, COSV55858869; called by muse, mutect2, varscan2
- URB2 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.084); catalogued as COSV50984866; called by muse, mutect2, varscan2
- UROD | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.5); catalogued as CM133454, COSV55800242; called by muse, mutect2, varscan2
- USP9X | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 48/72 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV61069137; called by muse, mutect2, varscan2
- WNT8B | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.597); catalogued as rs770539213, COSV59325318; called by muse, mutect2, varscan2
- WSCD2 | c.1558C>T p.R520C | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54578014; called by muse, mutect2, varscan2
- ZNF260 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72951199; called by muse, mutect2, varscan2
- ZNF786 | c.2183C>A p.P728H | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV60276062, COSV60277397; called by muse, mutect2, varscan2
- ZNF791 | c.1216C>A p.H406N | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58480953; called by muse, mutect2, varscan2
- CENPE | c.7163del p.N2388Ifs*18 | Frame Shift Del (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
- CPSF3 | c.323_328del p.S108_D109del | In Frame Del (DEL) | VAF 38/123 reads (31%) | called by mutect2, pindel, varscan2
- EFCAB5 | c.2762dup p.P922Afs*24 | Frame Shift Ins (INS) | VAF 15/81 reads (19%) | called by mutect2, pindel, varscan2
- LRBA | c.1611dup p.S538Ifs*4 | Frame Shift Ins (INS) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- PDE4DIP | c.1927del p.M643Wfs*10 | Frame Shift Del (DEL) | VAF 57/209 reads (27%) | called by mutect2, pindel, varscan2
- PRAMEF20 | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 112/415 reads (27%) | called by muse, mutect2, varscan2
- PROSER1 | c.1815del p.M606* | Frame Shift Del (DEL) | VAF 62/192 reads (32%) | called by mutect2, pindel, varscan2
- SH3TC1 | c.2329_2331del p.T777del | In Frame Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- ZNF3 | c.841dup p.E281Gfs*5 | Frame Shift Ins (INS) | VAF 24/108 reads (22%) | called by mutect2, pindel, varscan2
- AGO1 | c.60G>A p.V20= | Silent (SNP) | VAF 30/105 reads (29%) | catalogued as COSV64595276; called by muse, mutect2, varscan2
- CDH6 | c.2184T>G p.T728= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV54069894; called by muse, mutect2, varscan2
- ENGASE | c.858C>G p.L286= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV56135518; called by muse, mutect2
- FANCL | c.432T>C p.S144= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as COSV52074506; called by muse, mutect2, varscan2
- FREM2 | c.8889C>G p.T2963= | Silent (SNP) | VAF 31/112 reads (28%) | catalogued as COSV54837776; called by muse, mutect2, varscan2
- FZR1 | c.501C>A p.P167= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV58051795; called by muse, mutect2, varscan2
- GC | c.1216C>T p.L406= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1482832073, COSV56737273; called by muse, mutect2, varscan2
- GIMAP6 | c.348C>T p.I116= | Silent (SNP) | VAF 27/131 reads (21%) | catalogued as rs776667788, COSV61033385; called by muse, mutect2, varscan2
- KDM4B | c.915T>C p.T305= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99345246; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2424G>A p.L808= | Silent (SNP) | VAF 3/38 reads (8%) | catalogued as rs1435245300, COSV51720245; called by muse, mutect2
- MYLK3 | c.1395G>A p.R465= | Silent (SNP) | VAF 54/104 reads (52%) | catalogued as COSV67364259; called by muse, mutect2, varscan2
- NR2E3 | c.730C>T p.L244= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV58908329; called by muse, mutect2, varscan2
- PCDHGA1 | c.2187A>G p.G729= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV65296466; called by muse, mutect2, varscan2
- RIPK3 | c.1473C>A p.P491= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV53475426; called by muse, mutect2, varscan2
- RPRD2 | c.228T>C p.N76= | Silent (SNP) | VAF 91/256 reads (36%) | catalogued as COSV100954714, COSV64816830; called by muse, mutect2, varscan2
- TAS1R2 | c.2361G>C p.L787= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV64744992; called by muse, mutect2, varscan2
- TMEM67 | c.1227T>C p.Y409= | Silent (SNP) | VAF 60/213 reads (28%) | catalogued as COSV60039370; called by muse, mutect2, varscan2
- TRIM36 | c.39C>T p.I13= | Silent (SNP) | VAF 45/124 reads (36%) | catalogued as COSV56690198; called by muse, mutect2, varscan2
- ZEB2 | c.2727C>T p.F909= | Silent (SNP) | VAF 59/169 reads (35%) | catalogued as COSV57956811; called by muse, mutect2, varscan2
- MIR124-3 | n.63G>A | RNA (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- ZBTB49 | c.*1T>G | 3'UTR (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100552290; called by muse, mutect2
